Somatic mutation profile of tumor specimen TCGA-QR-A7IN-01A (aliquot TCGA-QR-A7IN-01A-11D-A35D-08) from TCGA case TCGA-QR-A7IN, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 52.7 years (19,237 days).
Specimen TCGA-QR-A7IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28b4341b-1bd6-48ca-805e-aeb328d708a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A7IN-10A (Blood Derived Normal), aliquot TCGA-QR-A7IN-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd73ef89-29ea-4aba-afb5-97ad9cf8bf79

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPAS1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 53/98 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55385154, COSV55385617; called by muse, mutect2, varscan2
- CHRNA9 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs759080788; called by muse, mutect2, varscan2
- ADGRG7 | c.1447C>G p.L483V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- AHDC1 | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DNAJC7 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RAB4B | c.21_34del p.L8Gfs*18 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel
- ADCY2 | c.2124C>A p.I708= | Silent (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- MDC1 | c.4602C>A p.A1534= | Silent (SNP) | VAF 28/182 reads (15%) | called by muse, mutect2
- SRRM2 | c.4917T>A p.G1639= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- VGLL1 | c.688+83G>C | Intron (SNP) | VAF 16/45 reads (36%) | catalogued as rs973201646; called by muse, mutect2
